Somatic mutation profile of tumor specimen 0DPE9X from CCDI case PBCDHR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 16.9 years (6,163 days).
Specimen 0DPE9X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beda0746-a1eb-432c-b117-c1a6267e406e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPE94 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc614c3d-6481-409f-bc62-872cb8e569d6

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, 5'UTR 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.13876G>A p.E4626K | Missense Mutation (SNP) | VAF 244/1568 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.485); catalogued as rs762871549; called by muse, mutect2, varscan2
- AKT3 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 39/549 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55608355; called by muse, mutect2
- ATP11C | c.1244G>C p.G415A | Missense Mutation (SNP) | VAF 31/1028 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100557601; called by muse, mutect2
- GJB3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 239/866 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs190198210; called by muse, mutect2, varscan2
- PRPF38A | c.710G>C p.R237P | Missense Mutation (SNP) | VAF 40/1163 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); catalogued as rs1250555888; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 48/1522 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- FBXO39 | c.1200+1G>A p.X400_splice | Splice Site (SNP) | VAF 34/892 reads (4%) | called by muse, mutect2
- MEGF8 | c.1367T>G p.L456R | Missense Mutation (SNP) | VAF 64/1516 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- SCUBE1 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 44/903 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 52/1322 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- MSN | c.669G>T p.L223= | Silent (SNP) | VAF 50/1150 reads (4%) | called by muse, mutect2
- HTN1 | c.-13-46T>A | Intron (SNP) | VAF 22/593 reads (4%) | called by muse, mutect2
- LPCAT2 | c.1315-84A>C | Intron (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- MMP26 | c.-145+92614C>T | Intron (SNP) | VAF 62/754 reads (8%) | catalogued as rs779261865, COSV100435054; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/248 reads (10%) | called by muse, varscan2
